Somatic mutation profile of tumor specimen 0DIW88 from CCDI case PBBWHU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.5 years (5,291 days).
Specimen 0DIW88: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16b1ff39-611f-4e3d-8f60-ca90859b76bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW6C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/712818b3-e45b-4a6d-a3fa-710c1133f6bd

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN6 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 177/521 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1252391264; called by muse, varscan2
- SIRPG | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 112/333 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs748098905; called by muse, varscan2
- CYLC1 | c.267C>A p.P89= | Silent (SNP) | VAF 54/444 reads (12%) | catalogued as COSV61415481; called by muse, varscan2
